Somatic mutation profile of tumor specimen TARGET-30-PALTYB-01A (aliquot TARGET-30-PALTYB-01A-01W) from TARGET case TARGET-30-PALTYB, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 4.2 years (1,536 days).
Specimen TARGET-30-PALTYB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22c3bf7c-1f2a-465d-b269-6f4cb5c72179.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PALTYB-10A (Blood Derived Normal), aliquot TARGET-30-PALTYB-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a22fcb3-4aa5-4ca0-b82f-f59759dbde3d

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Frame Shift Ins 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL27A1 | c.3365dup p.G1123Rfs*47 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | catalogued as rs1431754712; called by pindel, varscan2
- SRFBP1 | c.472T>G p.L158V | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV59583530; called by muse, mutect2, varscan2
- CRYL1 | c.530A>G p.K177R | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); called by muse, mutect2
- DLG2 | c.345dup p.T116Dfs*3 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by pindel, varscan2
- MAST4 | c.5801A>T p.D1934V (on ENST00000403625 / NM_001164664.2; = p.D1745V on NM_015183.3) | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); called by muse, mutect2
- PLEKHG6 | c.892G>T p.G298W | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- WDR59 | c.1522C>G p.L508V | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2
- ATP2B3 | c.3342+4613C>G | Intron (SNP) | VAF 10/206 reads (5%) | called by muse, mutect2
